FM case AD3174 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adnexal and Skin Appendage Neoplasms; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/62063c20-c2d8-4c32-bea2-2b5d69474b99

Male, 35.3 years: Adnexal carcinoma (ICD-O-3 8390/3) of the skin; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
